Somatic mutation profile of tumor specimen SM-JU34B (aliquot 7316UP-662) from CPTAC case C204057, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU34B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 768c0b13-8568-4d62-8605-1a9ff333ce25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105284 (Blood Derived Normal), aliquot 7316UP-302-1105284; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e6cc9bf-4805-4651-82e7-e2ba6f150815

The open-access MAF lists 51 somatic variants for this specimen: 28 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 18, Nonsense Mutation 3, Splice Site 2, 3'UTR 2, RNA 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2
- ALAS1 | c.1330+1G>A p.X444_splice | Splice Site (SNP) | VAF 5/57 reads (9%) | catalogued as rs1469355365; called by muse, mutect2
- ARMCX2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs782307127, COSV100168205; called by muse, mutect2, varscan2
- CBLL2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100081584; called by muse, mutect2, varscan2
- CDH9 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as rs779923057, COSV50275360, COSV50343795; called by mutect2, varscan2
- CR1 | c.2606T>C p.I869T | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65456805; called by muse, mutect2
- DGKQ | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs752503518, COSV53281525; called by muse, varscan2
- DSG2 | c.2084C>T p.T695M | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs200137091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.10204C>T p.R3402W | Missense Mutation (SNP) | VAF 58/350 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs141655789; called by muse, mutect2, varscan2
- GPR31 | c.4C>G p.P2A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV64761869; called by muse, mutect2, varscan2
- IQCF1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs752889161, COSV58823372; called by muse, mutect2, varscan2
- OR51E1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200993659, COSV67810326; called by mutect2, varscan2
- PPP1R3F | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs782455380; called by muse, mutect2, varscan2
- PRKAG2 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs200392688; ClinVar: uncertain significance; called by muse, mutect2
- PWWP3B | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1250645990; called by muse, mutect2, varscan2
- RELB | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs775189147, COSV55508233; called by muse, mutect2, varscan2
- SCN10A | c.3797G>T p.G1266V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs752189483; called by muse, mutect2, varscan2
- SLC6A8 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs782326194; called by muse, mutect2, varscan2
- SSPN | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs745893300; called by muse, mutect2, varscan2
- ANOS1 | c.1355-2A>G p.X452_splice | Splice Site (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- GRM1 | c.609G>C p.R203S | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HCFC1 | c.5141C>T p.T1714I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNQ3 | c.1082A>G p.E361G | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIFC3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2
- NRK | c.2620G>T p.G874* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- PITPNM1 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THAP9 | c.1714del p.L572* | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | called by mutect2, pindel, varscan2
- ZNF195 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CDH7 | c.1965C>T p.D655= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs116347805, COSV59889152; called by muse, varscan2
- CLCN5 | c.42T>C p.Y14= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs1557191337; called by mutect2, varscan2
- DCAF12L2 | c.306G>A p.A102= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV63582487, COSV63584428; called by muse, mutect2, varscan2
- FAM83E | c.1101G>A p.P367= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs532162334; called by muse, mutect2, varscan2
- FLNC | c.2271C>T p.N757= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs779105468; called by muse, mutect2, varscan2
- IGKV1D-42 | c.81C>A p.T27= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- KMT2E | c.3537T>C p.F1179= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs137965134; called by muse, varscan2
- PALM2AKAP2 | c.246T>C p.G82= (on ENST00000259318 / NM_001136562.3; = p.G313= on NM_007203.5) | Silent (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- PCDH7 | c.1164C>A p.R388= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV62342343; called by muse, mutect2, varscan2
- PCDHB15 | c.1893C>T p.S631= | Silent (SNP) | VAF 39/292 reads (13%) | called by muse, mutect2, varscan2
- PCLO | c.10737A>G p.Q3579= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2
- PDCD7 | c.1047G>A p.T349= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs147295901; called by muse, mutect2, varscan2
- PDZD4 | c.1893C>T p.D631= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV51251460; called by muse, mutect2, varscan2
- PHF3 | c.4731A>T p.S1577= | Silent (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- PIK3AP1 | c.1432C>A p.R478= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV59531507, COSV59531568; called by muse, mutect2, varscan2
- SIRPA | c.696C>T p.H232= | Silent (SNP) | VAF 28/218 reads (13%) | catalogued as rs769493586, COSV61537567; called by muse, mutect2, varscan2
- SLC17A9 | c.1095G>A p.P365= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs756409472, COSV64848272; called by muse, mutect2, varscan2
- TRIM6 | c.279A>G p.K93= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs139606995; called by muse, mutect2, varscan2
- CCL4L2 | c.191+88G>A | Intron (SNP) | VAF 9/56 reads (16%) | catalogued as rs755259101; called by muse, mutect2, varscan2
- DSCR8 | n.401G>A | RNA (SNP) | VAF 9/69 reads (13%) | catalogued as rs61748275; called by muse, mutect2, varscan2
- MIR508 | n.35G>T | RNA (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2
- MRPL54 | c.*34G>A | 3'UTR (SNP) | VAF 12/80 reads (15%) | catalogued as rs766782435; called by muse, mutect2
- TDRD6 | c.*3G>A | 3'UTR (SNP) | VAF 6/66 reads (9%) | catalogued as rs749611205, COSV51267111; called by muse, mutect2, varscan2
